Surgical pathology report (de-identified scan), TCGA case TCGA-AG-4007, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-4007-01A (Primary Tumor).

Diagnosis (diagnoses):

Resected colon sample with an ulcerated, moderately differentiated adenocarcinoma of the colorectal type, located 3.5 cm from the aboral resection margin, with broad infiltration of the pericolic fatty tissue, circumscribing an adjoining seminal vesicle. There are five local lymph node metastases. Tumor-free colon resection margins. The minimum distance of the tumor to the circumferential resection margin is 0.2 cm.

The tumor stage is: pT4, pN2 (5/34), pM1 (clinical liver metastases); G2, L1, V0, clinically R2

Source: NCI Genomic Data Commons file dafd670b-1a59-420b-a5e2-f5d5fbf9bcde (TCGA-AG-4007.CCB3D6C4-3562-4A91-A1F8-AFA6600532F0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).